Somatic mutation profile of tumor specimen TCGA-A7-A6VY-01A (aliquot TCGA-A7-A6VY-01A-12D-A33E-09) from TCGA case TCGA-A7-A6VY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 48.3 years (17,640 days).
Specimen TCGA-A7-A6VY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 502c0672-7f7f-42a4-aaa1-4dd2bf236cc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A6VY-10A (Blood Derived Normal), aliquot TCGA-A7-A6VY-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7b78d83-d2ea-4ada-a1d6-bce06cedde85

The open-access MAF lists 103 somatic variants for this specimen: 83 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 17, Frame Shift Del 5, Nonsense Mutation 3, Intron 1, RNA 1, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP8 | c.742C>T p.R248W (on ENST00000432109 / NM_033355.3; = p.R265W on NM_001228.4) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs17860424, CM023571, COSV51855342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMACR | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs774406448, COSV56869837; called by muse, mutect2, varscan2
- ARHGEF4 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58124789; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.469); catalogued as COSV99133636; called by muse, mutect2, varscan2
- CD276 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.349); catalogued as COSV100573277; called by muse, mutect2, varscan2
- CDH26 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99721756, COSV99721851; called by muse, mutect2, varscan2
- CDK18 | c.779T>A p.L260Q (on ENST00000506784 / NM_212503.3; = p.L230Q on NM_002596.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773913; called by muse, mutect2, varscan2
- CHAT | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); catalogued as rs1349499470, COSV100339694; called by mutect2, varscan2
- COG1 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100245118; called by muse, mutect2, varscan2
- CYP3A5 | c.1502G>C p.G501A | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); catalogued as COSV99769479; called by muse, mutect2, varscan2
- DENND5B | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs751889421, COSV100170823; called by muse, mutect2, varscan2
- DLG2 | c.2589G>A p.W863* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54642351, COSV99712529; called by muse, mutect2, varscan2
- EDDM3A | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.766); catalogued as COSV100473285; called by muse, mutect2, varscan2
- EPHA6 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748675557, COSV67564911; called by muse, mutect2, varscan2
- ESYT1 | c.1521T>G p.I507M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV99919639; called by muse, mutect2, varscan2
- FAM83A | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.266); catalogued as COSV99413980; called by muse, mutect2, varscan2
- FKBP2 | c.222G>C p.Q74H | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100501726; called by muse, mutect2
- GBE1 | c.249T>A p.D83E | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV101450072; called by muse, mutect2, varscan2
- GDAP1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99619302; called by muse, mutect2, varscan2
- HOOK2 | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV99244201; called by muse, mutect2, varscan2
- HOOK2 | c.2016G>T p.M672I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV99244202, COSV99244442; called by muse, mutect2, varscan2
- HRNR | c.8317G>A p.G2773S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs745519134, COSV64257975; called by muse, mutect2, varscan2
- IFT52 | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs754799617, COSV100887537; called by muse, mutect2, varscan2
- IL20RA | c.1419A>T p.E473D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100359794; called by muse, mutect2, varscan2
- ITGB3 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101457530; called by muse, mutect2, varscan2
- KIAA1549 | c.3483C>A p.N1161K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99649755; called by muse, mutect2, varscan2
- KIF24 | c.1734G>C p.L578F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.896); catalogued as COSV100799099; called by muse, mutect2, varscan2
- LXN | c.326G>C p.R109T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV99962656; called by muse, mutect2, varscan2
- MAGEA10 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99726564; called by muse, mutect2, varscan2
- MCMBP | c.1880G>A p.R627K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV100739977; called by muse, mutect2
- MIA2 | c.2111T>G p.F704C | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV54491675, COSV99697261; called by muse, mutect2, varscan2
- MMP17 | c.998G>C p.S333T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1332291099, COSV100861859; called by muse, mutect2, varscan2
- MPP4 | c.1732C>G p.Q578E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.268); catalogued as COSV99635518; called by muse, mutect2, varscan2
- MYO3A | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV56350467, COSV99778246; called by muse, mutect2, varscan2
- MYO7B | c.3913C>G p.L1305V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101267873; called by muse, mutect2, varscan2
- MYOF | c.1168G>C p.D390H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100825183; called by mutect2, varscan2
- NBN | c.593C>A p.P198Q | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99619003; called by muse, mutect2
- NCK2 | c.568A>G p.N190D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs1479928639, COSV99255169; called by muse, mutect2, varscan2
- NCKAP5 | c.3826C>G p.H1276D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100489957; called by muse, mutect2, varscan2
- NEXMIF | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.417); catalogued as COSV50024189, COSV99279571; called by muse, mutect2, varscan2
- NF1 | c.374G>C p.R125P | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.567); catalogued as COSV100645996; called by muse, mutect2, varscan2
- NOD2 | c.2302A>T p.K768* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100318200; called by muse, mutect2, varscan2
- NOL11 | c.1337C>G p.A446G | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV99474823; called by muse, mutect2, varscan2
- NOTCH2 | c.4163G>C p.S1388T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99862693; called by muse, mutect2, varscan2
- OR2AE1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100318277; called by muse, mutect2, varscan2
- OR2L3 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs1335750107, COSV63455465; called by muse, mutect2
- OR9Q1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100109332, COSV59039630; called by muse, mutect2, varscan2
- PARD3B | c.992C>G p.A331G | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.114); catalogued as COSV100592106; called by muse, mutect2, varscan2
- PLA2G4A | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV100820358; called by muse, mutect2, varscan2
- PTBP3 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 53/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs758330900, COSV52956290; called by muse, mutect2, varscan2
- RAPGEF6 | c.2732C>T p.T911I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99725156; called by muse, mutect2, varscan2
- RNF207 | c.26T>A p.L9Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs369840055; called by muse, mutect2
- RPGRIP1 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); catalogued as rs767741040; called by muse, mutect2, varscan2
- SCN1A | c.2651G>A p.G884D (on ENST00000303395 / NM_001202435.3; = p.G873D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as CM166598, COSV100319215, COSV57667482; called by muse, mutect2, varscan2
- SCRIB | c.1576C>G p.P526A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs1040022817, COSV100252493; called by muse, mutect2
- SEMA4B | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202959; called by muse, mutect2, varscan2
- SH3PXD2B | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100287649; called by muse, mutect2
- SLC24A1 | c.2782G>A p.V928I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs536096021, COSV99978017; ClinVar: uncertain significance; called by mutect2, varscan2
- SMURF2 | c.1379C>G p.S460* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99300301; called by muse, mutect2, varscan2
- SPTBN5 | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100310619; called by muse, mutect2, varscan2
- SSRP1 | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53479534, COSV99554714; called by muse, mutect2, varscan2
- STAB2 | c.4981T>G p.Y1661D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101185606; called by muse, mutect2, varscan2
- TATDN3 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs761487531, COSV100875175; called by muse, mutect2, varscan2
- THSD4 | c.1786A>G p.R596G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99964408; called by muse, mutect2, varscan2
- TRPM2 | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV100308176; called by muse, mutect2, varscan2
- TSPAN2 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.526); catalogued as COSV101049790; called by muse, mutect2, varscan2
- TTLL4 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs138326187, COSV51434844, COSV51437494; called by muse, mutect2, varscan2
- TUFT1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs751924952, COSV100777007; called by muse, mutect2
- UBTF | c.1964G>C p.S655T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV100255768; called by muse, mutect2, varscan2
- USE1 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV99812344; called by muse, mutect2, varscan2
- WDR76 | c.1691T>C p.I564T | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99776081; called by muse, mutect2, varscan2
- ZC3H12A | c.925G>C p.G309R | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100897638; called by muse, mutect2, varscan2
- ZFHX4 | c.9948G>T p.L3316F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99255750; called by muse, mutect2, varscan2
- ZMIZ1 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100565870; called by muse, mutect2, varscan2
- ZNF502 | c.751C>G p.H251D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99939551; called by muse, mutect2, varscan2
- APOBEC3B | c.1046_1077del p.V349Gfs*71 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel, varscan2
- ATXN7 | c.402_411del p.I135Sfs*85 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- DYNC2H1 | c.2850_2878del p.E951Pfs*8 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel
- GOLIM4 | c.1453_1467del p.A485_D489del | In Frame Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- PIKFYVE | c.292_319del p.E98* | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- PTPRT | c.3331_3352del p.D1111Sfs*68 | Frame Shift Del (DEL) | VAF 19/86 reads (22%) | called by mutect2, pindel
- TP53 | c.893dup p.L299Afs*7 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, pindel, varscan2
- TRAJ38 | c.60T>A p.N20K | Missense Mutation (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- CCDC142 | c.1857G>A p.E619= (on ENST00000393965 / NM_001365575.2; = p.E612= on NM_032779.4) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99251976; called by muse, mutect2, varscan2
- CNBD1 | c.564G>A p.L188= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV101575270; called by muse, mutect2, varscan2
- CPSF1 | c.1203G>A p.Q401= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs370225345; called by muse, mutect2, varscan2
- DAGLB | c.186C>T p.L62= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99765658; called by muse, mutect2, varscan2
- DLG2 | c.2223G>A p.E741= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99712532; called by muse, mutect2, varscan2
- DSCAM | c.4818C>A p.V1606= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV101259045; called by muse, mutect2, varscan2
- FGF10 | c.489C>G p.T163= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs755749426, COSV99240064, COSV99240450; called by muse, mutect2, varscan2
- GLMP | c.666G>C p.L222= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55294555, COSV99827730; called by muse, mutect2, varscan2
- IFT140 | c.1545C>G p.L515= | Silent (SNP) | VAF 40/138 reads (29%) | catalogued as COSV101276289, COSV68492449; called by muse, mutect2, varscan2
- KLHL18 | c.336G>T p.L112= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99230490; called by muse, mutect2, varscan2
- KRT2 | c.321C>A p.G107= | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as rs752401226, COSV59011788; called by muse, mutect2, varscan2
- LRP1 | c.13044C>T p.L4348= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs755788058, COSV54518278, COSV54525648; called by muse, mutect2, varscan2
- NSD1 | c.3813G>A p.K1271= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs757401535, COSV100728395; called by muse, mutect2, varscan2
- SSTR5 | c.519G>A p.P173= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs768486571, COSV99559491; called by muse, mutect2, varscan2
- TBPL2 | c.214C>T p.L72= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1357460984, COSV99905282; called by muse, mutect2, varscan2
- TRIM74 | c.612G>C p.L204= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99590230; called by muse, mutect2, varscan2
- XAB2 | c.30C>T p.P10= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs751055113, COSV100221980; called by muse, mutect2, varscan2
- C1orf220 | n.735_749del | RNA (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- FCGR2B | c.646+258A>G | Intron (SNP) | VAF 64/184 reads (35%) | catalogued as COSV99374841; called by muse, mutect2
- RNF8 | c.*32_*49del | 3'UTR (DEL) | VAF 13/27 reads (48%) | called by mutect2, pindel, varscan2
